Gene-level copy-number profile of tumor specimen C3L-09561-03 from CPTAC case C3L-09561, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 68.2 years (24,907 days).
Specimen C3L-09561-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a1069c8c-23f0-4dfe-b4f3-39a87ac252bc.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-09561-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,761 have no estimate.
https://portal.gdc.cancer.gov/files/2c277693-425d-49a7-aae2-f10d3e807af0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 135; copy number 1: 70; copy number 2: 22,130; copy number 3: 13,770; copy number 4: 18,418; copy number 5: 2,056; copy number 6: 1,712; copy number 7: 79; copy number 8: 138; copy number 9: 53; copy number 10: 122; copy number 11: 6; copy number 12: 32; copy number 13: 39; copy number 14: 78; copy number 16: 2; copy number 17: 22.

Homozygous deletions (total copy number 0; autosomes only): 99 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:130,048,143–130,055,920, 1 gene: AC083906.4.
- chr8:12,341,426–12,388,296, 5 genes: DEFB108E, ZNF705CP, FAM66A, AC087203.1, AC087203.2.
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.
- chr9:40,105,822–40,153,147, 4 genes: AL773545.3, CDRT15P14, AL773545.1, AL773545.2.
- chr9:40,992,249–41,218,410, 1 gene (within-gene range 0–2): FRG1HP.
- chr9:41,100,793–41,573,606, 14 genes: BX255923.2, FOXD4L6, CBWD6, MIR4477A, RNA5SP530, AL845472.1, PTGER4P2-CDK2AP2P2, CDK2AP2P1, MYO5BP1, AL354718.2, CDRT15P6, AL354718.1, AL591926.3, SNORA70.
- chr9:64,705,734–64,889,063, 7 genes: BMS1P11, AL359955.2, IGKV1OR-2, BNIP3P4, AL359955.1, AC125634.1, RNU6-1293P.
- chr9:68,228,651–68,644,442, 14 genes: AL353608.2, CBWD3, AL353608.4, FOXD4L3, AL353608.3, AL353608.1, PGM5, PGM5-AS1, AL161457.2, AL161457.1, TMEM252, TMEM252-DT, LINC01506, AL353616.1.
- chr9:68,788,307–68,789,670, 1 gene (within-gene range 0–2): AL354794.2.
- chr15:21,843,750–21,877,735, 3 genes: MIR3118-4, POTEB, RNU6-631P.
- chr18:51,028,394–55,839,184, 45 genes (within-gene range 0–4): SMAD4, SRSF10P1, MEX3C, RNU1-46P, LINC01630, SS18L2P2, AC109315.1, RSL24D1P9, AC027216.1, RPS8P3, AC016383.1, DCC, AC011155.1, VN1R76P, MIR4528, LINC01917, LINC01919, RPL29P32, AC090666.1, MBD2, SNORA37, AC093462.1, POLI, STARD6, C18orf54, SNRPGP2, AC090897.1, AC091135.1, DYNAP, RAB27B, RPSAP57, AC007673.1, AC098848.1, CCDC68, MAP1LC3P, LINC01929, RNA5SP459, TCF4, TCF4-AS1, MIR4529, TCF4-AS2, AC022031.2, RPL21P126, LINC01415, AC022031.1.
- chr19:20,416,514–20,571,095, 3 genes (within-gene range 0–2): BNIP3P22, AC008554.1, BNIP3P23.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,339 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:38,474,825–42,817,397, 127 genes, copy number 5–13 (within-gene range 3–13) (broad region; genes not listed).
- chr1:50,024,029–50,327,007, 5 genes, copy number 5: ELAVL4, AL583843.1, ELAVL4-AS1, AL592182.1, AL596275.1.
- chr2:86,907,953–87,825,952, 27 genes, copy number 5 (within-gene range 4–5): RGPD1, WBP1P1, NDUFB4P5, PLGLB1, ANAPC1P2, ANAPC1P2, AC092651.1, ANAPC1P3, AC083899.1, MIR4771-1, CENPNP1, LINC01955, DBF4P3, AC068279.2, IGKV3OR2-268, AC068279.1, LINC01943, CYTOR, AC133644.2, AC133644.1, PAFAH1B1P1, MIR4435-1, RPS14P5, ANAPC1P4, PLGLB2, RGPD2, MTATP8P2.
- chr2:96,497,646–96,532,306, 2 genes, copy number 6: NEURL3, AC013270.1.
- chr3:195,650,146–195,811,973, 8 genes, copy number 5: AC233280.2, AC233280.1, MUC20-OT1, SDHAP2, MIR570, SMBD1P, MUC20, MUC4.
- chr5:58,198–45,895,970, 679 genes, copy number 5–6 (broad region; genes not listed).
- chr7:85,636,013–119,179,149, 600 genes, copy number 5–7 (broad region; genes not listed).
- chr8:71,197,433–145,066,685, 1,126 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr9:39,748,514–39,892,895, 5 genes, copy number 6: GLIDR, BX664615.1, RN7SL763P, SNORA70, CR769767.1.
- chr9:93,576,584–93,679,587, 2 genes, copy number 6: PHF2, MIR548AU.
- chr10:27,313,723–27,414,368, 8 genes, copy number 5: AL355493.6, RNU6-666P, AL355493.1, RNU6-452P, LINC02673, FAM210CP, TRIAP1P1, PTCHD3.
- chr11:37,702,125–43,920,944, 56 genes, copy number 5–12: AC061997.1, RPL7AP56, LINC02760, AC103798.1, LRRC6P1, AC021713.1, LINC02759, LINC01493, AC021723.2, AC021723.1, RNU6-99P, AC021749.1, AC021820.1, AC080100.1, LRRC4C, Y_RNA, AC090720.1, RNU6-365P, AC090138.1, LINC02741, AC021006.1, AC021006.2, LINC01499, AC023442.1, AC023442.3, AC023442.2, LINC02745, LINC02740, AC109810.1, AC009643.2, AC009643.1, HNRNPKP3, API5, AC087276.2, Y_RNA, TTC17, AC087276.3, AC087276.1, RN7SKP287, PPIAP41, CTBP2P6, AC068205.1, MIR670, MIR670HG, AC068205.2, MIR129-2, HSD17B12, AC068205.3, RPL23AP63, PHBP2, AC068205.4, AC087521.2, AC087521.4, ALKBH3, SEC14L1P1, ALKBH3-AS1.
- chr11:43,925,342–43,947,206, 2 genes, copy number 12 (within-gene range 4–12): C11orf96, AC087521.1.
- chr14:28,318,141–53,023,597, 390 genes, copy number 6–14 (broad region; genes not listed).
- chr15:21,293,653–21,307,855, 2 genes, copy number 5: AC068446.1, RNU6-1235P.
- chr16:65,141,751–82,575,518, 502 genes, copy number 5 (within-gene range 5–8) (broad region; genes not listed).
- chr17:35,561,539–43,305,397, 425 genes, copy number 6–13 (broad region; genes not listed).
- chr18:49,650,350–49,813,953, 3 genes, copy number 8 (within-gene range 4–8): SMUG1P1, AC090227.3, ACAA2.
- chr20:39,757,202–55,684,915, 328 genes, copy number 5–17 (broad region; genes not listed).
- chr22:18,178,038–19,034,564, 42 genes, copy number 5: FAM230D, GGTLC5P, FAM230J, AC011718.1, PPP1R26P3, FAM230A, AC023490.2, FAM247B, GGTLC3, Metazoa_SRP, AC023490.3, TMEM191B, PI4KAP1, AC023490.1, RN7SKP131, RIMBP3, Metazoa_SRP, SUSD2P2, CA15P2, PPP1R26P2, PPP1R26P4, FAM230E, GGT3P, AC008132.2, E2F6P1, AC008132.1, BCRP7, FAM230F, AC008103.1, DGCR6, AC007326.4, PRODH, AC007326.5, AC007326.2, DGCR5, AC007326.3, DGCR5, AC007326.1, AC000095.2, AC000095.1, FAM246C, CA15P1.

Autosomal genes at a single copy (total copy number 1): 70. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
